Somatic mutation profile of tumor specimen MP2PRT-PAUSIG-TMP1-A (aliquot MP2PRT-PAUSIG-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUSIG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.1 years (2,971 days).
Specimen MP2PRT-PAUSIG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34507d27-f8b2-40fc-a0db-852f7550804f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUSIG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUSIG-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05f65864-afe6-4ad0-a251-79b8af70504c

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, Frame Shift Ins 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB1 | c.2539G>A p.V847I | Missense Mutation (SNP) | VAF 186/434 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.239); catalogued as rs371147537; called by muse, varscan2
- CSRNP3 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 130/293 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs371859963; called by muse, mutect2, varscan2
- FBXW5 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 371/840 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs371147879, COSV56403693, COSV99812276; called by muse, mutect2, varscan2
- L3MBTL4 | c.1504C>T p.H502Y | Missense Mutation (SNP) | VAF 64/437 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.942); catalogued as COSV53131034; called by muse, mutect2, varscan2
- LCE2A | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 164/615 reads (27%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs371565593; called by muse, mutect2, varscan2
- PIK3C2A | c.3950G>T p.C1317F | Missense Mutation (SNP) | VAF 226/547 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV56406955; called by muse, mutect2, varscan2
- WDR3 | c.512C>A p.T171N | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as COSV100832118; called by muse, varscan2
- DDX5 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 199/507 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EZHIP | c.557G>C p.C186S | Missense Mutation (SNP) | VAF 10/336 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2
- PITPNM1 | c.178C>G p.H60D | Missense Mutation (SNP) | VAF 241/536 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRGV2 | c.353_354del p.G118del | Frame Shift Del (DEL) | VAF 48/172 reads (28%) | called by mutect2, pindel*
- XPO1 | c.1172_1173insGGGC p.P392Gfs*11 | Frame Shift Ins (INS) | VAF 94/273 reads (34%) | called by mutect2, pindel, varscan2
- CHMP4C | c.423C>T p.I141= | Silent (SNP) | VAF 106/291 reads (36%) | catalogued as rs370069091; called by muse, mutect2, varscan2
